TCGA case TCGA-16-0850 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Toronto Western Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/389d5472-9e4a-47b3-bd6c-994eb0fafea2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 52 years; Vital status: Dead; Days to death: 498 days (1.4 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 52.8 years (19,281 days); Year of diagnosis: 2007; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 20 days; Days to treatment end: 66 days; Treatment dose: 6,020 cGy; Number of fractions: 30; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 476 days (1.3 years); Days to treatment end: 489 days (1.3 years); Treatment dose: 1,200 cGy; Number of fractions: 10.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 53.0 years (19,364 days); Days to diagnosis: 83 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 83 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 83 days.
- Days to follow up: 496 days (1.4 years); Disease response: With Tumor.
- Days to follow up: 498 days (1.4 years); Disease response: With Tumor.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-16-0850-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.4; Intermediate dimension: 0.5; Shortest dimension: 0.4.
  Slide TCGA-16-0850-01A-01-TS2: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 98; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-16-0850-01A-01-BS1: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 98; Percent necrosis: 2; Percent stromal cells: 3.
- Sample TCGA-16-0850-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Radiation treatment 1: Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: T spine.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 498 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 498 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 83 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-16-0850-01A-01D-0384-01): tumor purity 1, ploidy 3.48, whole-genome doublings 1.
